Somatic mutation profile of tumor specimen TCGA-QR-A70T-01A (aliquot TCGA-QR-A70T-01A-11D-A35D-08) from TCGA case TCGA-QR-A70T, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 40.5 years (14,780 days).
Specimen TCGA-QR-A70T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a0fbf55-e838-4157-8591-f61976c92ee3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A70T-10A (Blood Derived Normal), aliquot TCGA-QR-A70T-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/374233fd-4c0b-4ec6-8bc2-b429dc525e9e

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 4, Frame Shift Del 2, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1S | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV61071093; called by muse, mutect2, varscan2
- FBP2 | c.40del p.L14* | Frame Shift Del (DEL) | VAF 35/107 reads (33%) | catalogued as COSV100942083, COSV64694678; called by mutect2, pindel, varscan2
- LRP6 | c.3133G>C p.G1045R | Missense Mutation (SNP) | VAF 79/182 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53786813; called by muse, mutect2, varscan2
- GANAB | c.561G>C p.S187= | Splice Region (SNP) | VAF 20/61 reads (33%) | called by muse, mutect2, varscan2
- HHIPL2 | c.1314_1317del p.R439Yfs*18 | Frame Shift Del (DEL) | VAF 6/76 reads (8%) | called by mutect2, pindel
- POC1B-GALNT4 | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- POLR1A | c.851A>T p.D284V | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CEBPZ | c.1068T>C p.D356= | Silent (SNP) | VAF 37/132 reads (28%) | catalogued as rs754495990, COSV50017534; called by muse, mutect2, varscan2
- HIPK1 | c.3081C>T p.T1027= | Silent (SNP) | VAF 46/94 reads (49%) | catalogued as rs766218728, COSV100479137; called by muse, mutect2, varscan2
- HTR6 | c.753C>T p.D251= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs745947620; called by muse, mutect2, varscan2
- MUC16 | c.39127C>T p.L13043= | Silent (SNP) | VAF 15/188 reads (8%) | called by muse, mutect2
- TLE1 | c.1660T>C p.L554= | Silent (SNP) | VAF 18/146 reads (12%) | catalogued as COSV64720546; called by muse, mutect2, varscan2
- FMN1 | c.2044-1653A>G | Intron (SNP) | VAF 52/113 reads (46%) | catalogued as COSV57923451; called by muse, mutect2, varscan2
